Gene-level copy-number profile of tumor specimen TCGA-77-8156-01A from TCGA case TCGA-77-8156, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 60.8 years (22,198 days).
Specimen TCGA-77-8156-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.476774bb-7385-42b4-9c75-386152c266e4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-77-8156-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8c3d33f7-f329-4d09-8eea-9dc36beb6386

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,347; copy number 2: 24,765; copy number 3: 14,964; copy number 4: 8,244; copy number 5: 3,234; copy number 6: 2,208; copy number 7: 1,886; copy number 8: 456; copy number 9: 213; copy number 10: 80; copy number 11: 66; copy number 14: 352.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-77-8156-01A-11D-2243-01): tumor purity 0.23, ploidy 2.96, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8,481 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:209,528,455–209,567,673, 2 genes, copy number 7 (within-gene range 4–7): AL023754.1, AL023754.2.
- chr2:22,338,886–83,657,842, 1,057 genes, copy number 6–7 (broad region; genes not listed).
- chr3:157,814,822–198,222,513, 711 genes, copy number 9–14 (broad region; genes not listed).
- chr5:23,013,048–44,828,592, 329 genes, copy number 5 (broad region; genes not listed).
- chr5:179,732,822–181,342,213, 78 genes, copy number 6 (broad region; genes not listed).
- chr6:167,607–30,148,735, 720 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr6:36,315,761–60,546,660, 443 genes, copy number 7 (broad region; genes not listed).
- chr7:70,972–145,040,941, 2,755 genes, copy number 6–8 (broad region; genes not listed).
- chr9:29,214,322–43,045,120, 396 genes, copy number 5 (broad region; genes not listed).
- chr12:18,242,961–30,802,602, 200 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr13:104,125,930–106,426,122, 15 genes, copy number 6: AL136524.1, RPL7P45, AL138954.1, DAOA-AS1, AL359751.2, AL359751.1, DAOA, AL359745.1, LINC00343, AL138701.1, AL138701.2, RNA5SP38, AL139379.1, LINC00460, RPL35P9.
- chr17:22,519,195–34,174,964, 340 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr18:47,390–43,499,836, 676 genes, copy number 5 (broad region; genes not listed).
- chr19:9,683,294–23,416,075, 759 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,823. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
